Gene-level copy-number profile of tumor specimen TCGA-AG-A02G-01A from TCGA case TCGA-AG-A02G, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 66.4 years (24,259 days).
Specimen TCGA-AG-A02G-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.3dc30230-ecc7-40ff-abab-3c614bf4b3b6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AG-A02G-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d63932c9-c251-416a-96cb-8ff2a779a479

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 433; copy number 1: 2,044; copy number 2: 17,219; copy number 3: 27,437; copy number 4: 10,246; copy number 5: 6; copy number 6: 1,393; copy number 7: 48; copy number 8: 273; copy number 9: 596; copy number 11: 117.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AG-A02G-01A-01D-A008-01): tumor purity 0.8, ploidy 3.05, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 342 genes in 93 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:7,771,296–7,781,432, 2 genes (within-gene range 0–2): VAMP3, Z98884.2.
- chr1:37,776,670–37,809,454, 6 genes: ACTN4P2, AL929472.1, MANEAL, AL929472.3, YRDC, C1orf122.
- chr1:42,036,143–42,051,784, 2 genes (within-gene range 0–2): AL158216.1, HNRNPFP1.
- chr1:47,416,285–47,440,691, 3 genes: FOXE3, FOXD2-AS1, FOXD2.
- chr1:64,972,225–65,058,508, 6 genes: LINC01359, SLC2A3P2, AL357078.2, RNU6-1176P, MIR3671, MIR101-1.
- chr1:109,483,479–109,509,738, 3 genes: ATXN7L2, CYB561D1, AMIGO1.
- chr2:64,450,096–64,461,381, 2 genes: AC008074.1, LGALSL.
- chr2:236,194,872–236,264,409, 2 genes (within-gene range 0–3): ASB18, RNU1-31P.
- chr3:71,675,414–71,786,425, 4 genes (within-gene range 0–3): EIF4E3, GPR27, PROK2, AC096970.1.
- chr4:7,030,554–7,057,952, 3 genes: AC097382.2, CCDC96, TADA2B.
- chr4:186,104,419–186,172,667, 2 genes (within-gene range 0–3): FAM149A, AC104070.1.
- chr5:127,511,464–127,555,085, 2 genes: HNRNPKP1, PRRC1.
- chr5:157,731,420–157,760,709, 3 genes (within-gene range 0–2): THG1L, LSM11, AC026407.1.
- chr7:149,422,675–149,497,817, 3 genes: AC073314.1, ZNF777, ZNF746.
- chr8:130,004,528–130,008,453, 2 genes: RNU7-181P, MIR5194.
- chr9:111,631,334–111,670,229, 3 genes (within-gene range 0–2): DNAJC25, DNAJC25-GNG10, GNG10.
- chr10:91,152,605–91,161,315, 2 genes: NUDT9P1, AL731553.1.
- chr11:6,603,642–6,658,396, 10 genes: AC091564.2, ILK, TAF10, AC091564.3, AC091564.7, TPP1, AC091564.6, DCHS1, AC091564.4, AC091564.5.
- chr11:23,403,805–23,419,190, 2 genes: WIZP1, MIR8054.
- chr11:74,738,478–74,746,114, 2 genes: AP001324.2, AP001324.1.
- chr12:120,904,702–120,915,123, 2 genes: AC069214.1, CLIC1P1.
- chr12:128,813,186–128,827,579, 2 genes: AC108704.2, AC108704.1.
- chr14:95,521,943–95,544,724, 3 genes (within-gene range 0–2): SNHG10, SCARNA13, GLRX5.
- chr14:105,093,609–105,315,589, 11 genes (within-gene range 0–2): LINC02298, AL512356.4, AL512356.3, AL512356.2, AL512356.5, JAG2, MIR6765, AL512356.1, NUDT14, BRF1, BTBD6.
- chr15:78,250,502–78,282,196, 2 genes (within-gene range 0–2): AC090607.3, DNAJA4.
- chr15:100,861,843–100,919,391, 5 genes (within-gene range 0–2): AC015712.4, AC015712.5, ALDH1A3, AC015712.7, AC015712.2.
- chr16:19,111,035–19,121,629, 2 genes: AC099518.6, ITPRIPL2.
- chr17:46,193,576–46,268,694, 5 genes: KANSL1-AS1, Y_RNA, MAPK8IP1P1, AC005829.2, AC005829.1.
- chr18:76,491,629–76,498,088, 2 genes: AC018413.1, ZNF516-DT.
- chr18:78,976,555–79,002,677, 2 genes: LINC01896, SALL3.
- chr19:48,198,107–48,214,751, 2 genes (within-gene range 0–3): AC011466.4, AC011466.1.
- chr20:603,797–675,802, 4 genes: TCF15, SRXN1, AL121758.1, SCRT2.
- chr20:14,933,843–15,022,958, 3 genes: AL138808.1, RNU6-1159P, RNU6-115P.
- chr21:36,966,461–36,986,851, 2 genes: AP000704.1, Y_RNA.
- chr21:39,313,935–39,349,647, 4 genes: BRWD1-AS2, BRWD1-AS1, HMGN1, Y_RNA.
- chr21:41,870,633–41,882,300, 3 genes: AP001619.2, AP001619.1, AP001619.3.
- chr22:17,116,297–17,132,104, 2 genes: TMEM121B, LINC01664.
- chr22:21,759,657–23,145,021, 145 genes (within-gene range 0–1) (broad region; genes not listed).
- chr22:31,925,519–31,957,603, 2 genes (within-gene range 0–2): C22orf24, YWHAH.
- chr22:50,541,108–50,801,309, 21 genes: U62317.3, KLHDC7B-DT, KLHDC7B, SYCE3, CPT1B, CHKB-CPT1B, CHKB, CHKB-DT, U62317.2, MAPK8IP2, ARSA, Y_RNA, AC000050.2, SHANK3, RNU6-409P, AC000036.1, ACR, AC002056.2, AC002056.1, RPL23AP82, RABL2B.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,031 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:110,871,188–115,089,503, 114 genes, copy number 11 (within-gene range 4–11) (broad region; genes not listed).
- chr20:28,563,850–57,711,536, 707 genes, copy number 8–9 (within-gene range 2–9) (broad region; genes not listed).
- chr20:57,895,394–64,313,132, 210 genes, copy number 7–8 (within-gene range 2–8) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,937. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
